Somatic mutation profile of tumor specimen 0DFXH0 from CCDI case PBBSEG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.3 years (825 days).
Specimen 0DFXH0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45c0f678-0f1c-4236-b0db-4c6c268c4e0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFXEV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf3c1f14-4fa2-4a79-98eb-4af461ecdd0c

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 2, Silent 2, Frame Shift Ins 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAD1 | c.16C>T p.H6Y | Missense Mutation (SNP) | VAF 32/1054 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV99635026; called by muse, mutect2
- CLEC4M | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 341/857 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs370560578, COSV50217617; called by muse, mutect2, varscan2
- GLI2 | c.3056C>T p.A1019V (on ENST00000361492 / NM_001374353.1; = p.A1036V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 290/1471 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs755093850, COSV58050100; called by muse, mutect2, varscan2
- ITPR1 | c.7450G>A p.G2484S (on ENST00000354582; = p.G2429S on NM_002222.7) | Missense Mutation (SNP) | VAF 241/1101 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs187571979, COSV57005920; called by muse, mutect2, varscan2
- KANSL1 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 121/1972 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1372472141; called by muse, mutect2
- NPFFR2 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 104/1134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100441444; called by muse, mutect2
- OR11H1 | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 96/2426 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs1308621306; called by muse, mutect2
- TNFRSF1A | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 345/932 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as rs199961053, COSV50828171; called by muse, mutect2, varscan2
- APOF | c.566T>A p.V189E | Missense Mutation (SNP) | VAF 53/972 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MALRD1 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 46/1202 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0.052); called by muse, mutect2
- OR51A4 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 488/1263 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA11 | c.2345A>G p.E782G | Missense Mutation (SNP) | VAF 100/1428 reads (7%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2
- PNPLA1 | c.1578dup p.P527Tfs*? (on ENST00000394571 / NM_001374623.1; = p.P432Tfs*14 on NM_173676.2) | Frame Shift Ins (INS) | VAF 784/2278 reads (34%) | called by mutect2, pindel, varscan2
- PPIP5K2 | c.2617C>T p.L873F | Missense Mutation (SNP) | VAF 574/1363 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RBM19 | c.1725T>A p.D575E | Missense Mutation (SNP) | VAF 255/899 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- RHPN1 | c.1499C>G p.S500C | Missense Mutation (SNP) | VAF 62/2074 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- SP140L | c.1295C>A p.P432Q | Missense Mutation (SNP) | VAF 560/1572 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- TUBA3C | c.226+1G>T p.X76_splice | Splice Site (SNP) | VAF 88/1660 reads (5%) | called by muse, mutect2
- CBX4 | c.609G>A p.G203= | Silent (SNP) | VAF 42/1081 reads (4%) | called by muse, mutect2
- EPPK1 | c.13956G>A p.E4652= | Silent (SNP) | VAF 58/1157 reads (5%) | called by muse, mutect2
- FRAS1 | c.5856+113A>T | Intron (SNP) | VAF 24/532 reads (5%) | called by muse, mutect2
- MBTPS1 | c.1448+76A>G | Intron (SNP) | VAF 73/669 reads (11%) | catalogued as rs1254066969; called by muse, mutect2, varscan2
- ZFYVE21 | chr14:103715809 C>T | 5'Flank (SNP) | VAF 62/598 reads (10%) | catalogued as rs773272090; called by muse, mutect2
